Somatic mutation profile of tumor specimen TCGA-BR-4191-01A (aliquot TCGA-BR-4191-01A-02D-1126-08) from TCGA case TCGA-BR-4191, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G2; Age at diagnosis: 72.7 years (26,562 days).
Specimen TCGA-BR-4191-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d424271-11fd-4464-98df-58d409609d7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4191-11A (Solid Tissue Normal), aliquot TCGA-BR-4191-11A-01D-1126-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05e54686-964f-48cd-9bd2-0149f2ac11d8

The open-access MAF lists 230 somatic variants for this specimen: 180 protein-altering or splice-affecting, 42 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 42, Frame Shift Del 11, Nonsense Mutation 9, Splice Site 6, Intron 5, In Frame Del 4, Splice Region 4, RNA 2, Translation Start Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPARC | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057517663, CM155190, COSV50558364, COSV50559487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3660G>T p.Q1220H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV59389742; called by muse, mutect2, varscan2
- ACSF3 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV58080025; called by muse, mutect2, varscan2
- ADAMTS16 | c.1412G>T p.W471L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56998608; called by muse, mutect2
- AP2M1 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53049165; called by muse, mutect2, varscan2
- ARAP3 | c.4283C>T p.T1428I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs375260150; called by muse, mutect2, varscan2
- ARMC6 | c.404G>T p.G135V (on ENST00000392336; = p.G110V on NM_033415.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99522881; called by muse, mutect2, varscan2
- ASB6 | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV52965489; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1553420693, COSV52270633; called by muse, mutect2, varscan2
- ATXN1 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55223303; called by muse, mutect2, varscan2
- B3GLCT | c.1316C>G p.P439R | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100587036, COSV58456897; called by muse, mutect2, varscan2
- BCL9 | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV52347608; called by muse, mutect2, varscan2
- BDP1 | c.5735A>C p.E1912A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV62430757, COSV62432830; called by muse, mutect2, varscan2
- BEST3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995301, COSV56995419; called by muse, mutect2, varscan2
- BMI1 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV64959365; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- CACNA1A | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1057524457, COSV64196421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAD | c.3305A>G p.Y1102C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV53029374; called by muse, mutect2, varscan2
- CAV1 | c.263G>C p.S88T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV61953904; called by muse, mutect2, varscan2
- CCDC122 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.028); catalogued as COSV55709851; called by muse, mutect2, varscan2
- CCDC39 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV56488972; called by muse, mutect2, varscan2
- CDK5RAP2 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV62576413; called by muse, mutect2, varscan2
- CEP192 | c.1823A>G p.Y608C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs989145384, COSV58062485; called by muse, mutect2, varscan2
- CFAP74 | c.4288G>A p.V1430I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs768524658; called by muse, mutect2, varscan2
- CHD9 | c.2677A>G p.I893V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV54613447; called by muse, mutect2, varscan2
- CHL1 | c.2467A>C p.S823R (on ENST00000397491 / NM_001253387.1; = p.S839R on NM_006614.4) | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1191411773, COSV56598866; called by muse, mutect2, varscan2
- COG5 | c.2086C>G p.R696G (on ENST00000347053 / NM_001379512.1; = p.R717G on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV51757728, COSV51765618; called by muse, mutect2, varscan2
- CSK | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV54974901; called by muse, mutect2, varscan2
- CSMD3 | c.2513G>C p.G838A (on ENST00000297405 / NM_001363185.1; = p.G734A on NM_052900.3) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52250069; called by muse, mutect2, varscan2
- CSRNP1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV56189175; called by muse, mutect2, varscan2
- CST4 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99462910; called by muse, mutect2, varscan2
- DCAF12L1 | c.508A>C p.N170H | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV64422325; called by muse, mutect2, varscan2
- DEPDC7 | c.935G>C p.S312T (on ENST00000241051 / NM_001077242.2; = p.S303T on NM_139160.2) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1199343789, COSV53808216; called by muse, mutect2, varscan2
- DMD | c.6845C>T p.P2282L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV58931190; called by muse, mutect2, varscan2
- DMD | c.490T>C p.S164P | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as COSV55887593; called by muse, mutect2, varscan2
- DMXL2 | c.4609T>A p.L1537M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51850970; called by muse, mutect2, varscan2
- DNAH17 | c.4907A>G p.K1636R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV67758493; called by muse, mutect2, varscan2
- DNAH2 | c.4440G>A p.W1480* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV66722780; called by muse, mutect2, varscan2
- DNAH7 | c.4914C>A p.N1638K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.715); catalogued as rs1316101455, COSV56757182, COSV56775103; called by muse, mutect2, varscan2
- DNER | c.1571T>A p.V524D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV59171380; called by muse, mutect2, varscan2
- DOCK2 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV99909635; called by muse, mutect2
- DOCK3 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56536232; called by muse, mutect2, varscan2
- DSG1 | c.2681T>G p.V894G | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57137603; called by muse, mutect2, varscan2
- DSG4 | c.1935G>T p.L645F | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57394608; called by muse, mutect2, varscan2
- DVL3 | c.1160C>A p.T387N | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.132); catalogued as COSV100493467; called by muse, mutect2, varscan2
- EDNRB | c.311C>T p.A104V (on ENST00000377211 / NM_001201397.1; = p.A14V on NM_000115.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.519); catalogued as rs548023225, COSV57519093; called by muse, mutect2, varscan2
- EEF1AKMT4 | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99955449; called by muse, mutect2, varscan2
- EFNB2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV55366349; called by muse, mutect2, varscan2
- ELMO2 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV51684597; called by muse, mutect2, varscan2
- ENOX1 | c.94G>C p.A32P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.503); catalogued as COSV54908759; called by muse, mutect2, varscan2
- FBN1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs534127494, CM1413444, COSV57310898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF12 | c.319A>C p.N107H (on ENST00000454309 / NM_021032.5; = p.N45H on NM_004113.6) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV53177831; called by muse, mutect2
- FGL2 | c.1241G>T p.S414I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV50383798; called by muse, mutect2, varscan2
- FIG4 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.244); catalogued as COSV100019934, COSV57789410; called by muse, mutect2, varscan2
- FLOT1 | c.1219A>C p.S407R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV58358054; called by muse, mutect2, varscan2
- FMNL1 | c.798C>A p.P266= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs1158753154, COSV100056037; called by muse, mutect2, varscan2
- FMOD | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs989612351, COSV61610401; called by muse, mutect2, varscan2
- FOXI1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs781004930, COSV60389314; called by muse, mutect2, varscan2
- FRMD7 | c.418A>T p.K140* | Nonsense Mutation (SNP) | VAF 122/147 reads (83%) | catalogued as COSV53747700; called by muse, mutect2, varscan2
- FSIP2 | c.16987C>T p.Q5663* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as rs746214525, COSV100553577; called by muse, mutect2, varscan2
- GAS8 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs756155808, COSV51943894; called by muse, mutect2, varscan2
- GIGYF1 | c.784G>C p.G262R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV51944577; called by muse, varscan2
- GP6 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.112); catalogued as COSV59978685; called by muse, mutect2, varscan2
- GPRASP1 | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64354760; called by muse, mutect2, varscan2
- GPRIN3 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV60885630; called by muse, mutect2, varscan2
- GRID1 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.997); catalogued as rs913727708, COSV60041299, COSV60058400; called by muse, mutect2, varscan2
- GUCY2C | c.1651G>T p.V551L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53792925; called by muse, mutect2, varscan2
- HARS1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56908220; called by muse, mutect2, varscan2
- HAUS3 | c.624G>C p.E208D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV54723480; called by muse, mutect2
- HOXB3 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV61144019, COSV61144447; called by muse, mutect2, varscan2
- ICAM3 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV50329490; called by muse, mutect2, varscan2
- IDNK | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV52892123; called by muse, mutect2, varscan2
- IFIT3 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.54); catalogued as rs113402097, COSV51079910; called by muse, mutect2, varscan2
- IGKV1-6 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as rs751472625; called by muse, mutect2, varscan2
- INKA1 | c.805A>T p.M269L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV60968088; called by muse, mutect2, varscan2
- ITIH5 | c.2174T>C p.I725T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV53670394; called by muse, mutect2
- ITPR1 | c.5728G>A p.E1910K (on ENST00000354582; = p.E1855K on NM_002222.7) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.358); catalogued as COSV56993195; called by muse, mutect2, varscan2
- KCNH2 | c.2551C>G p.H851D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51210106; called by muse, mutect2, varscan2
- KCNJ1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs780690034, COSV60662313; called by muse, mutect2, varscan2
- KIDINS220 | c.3023A>T p.N1008I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56756498; called by muse, mutect2, varscan2
- KNTC1 | c.2475G>T p.M825I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV61082086; called by muse, mutect2, varscan2
- KRT2 | c.1427A>T p.E476V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs60537449, CM994123, COSV59011614; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT34 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as rs1394197370, COSV101222518; called by muse, varscan2
- KRT37 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56659045; called by muse, mutect2, varscan2
- KRT79 | c.675C>A p.D225E | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV57941261; called by muse, mutect2, varscan2
- L3MBTL1 | c.1632G>C p.K544N (on ENST00000418998 / NM_001377303.1; = p.K454N on NM_015478.7) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64229112; called by muse, mutect2, varscan2
- LCOR | c.1202G>T p.R401I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53717314, COSV53717365; called by muse, mutect2, varscan2
- LRP2 | c.10069T>A p.S3357T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.038); catalogued as COSV55563889; called by muse, mutect2, varscan2
- LUC7L2 | c.1007C>G p.S336* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV54928299; called by muse, mutect2, varscan2
- LYZL4 | c.323T>G p.I108S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55104685; called by muse, mutect2, varscan2
- MACF1 | c.1031A>C p.Q344P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | catalogued as COSV58387947; called by muse, mutect2, varscan2
- MATN4 | c.1382G>A p.R461H (on ENST00000372754; = p.R420H on NM_003833.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen probably damaging (0.913); catalogued as rs376998707; called by mutect2, varscan2
- MBD3L1 | c.206G>T p.R69M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV59776191; called by muse, mutect2, varscan2
- MECOM | c.1414G>C p.D472H (on ENST00000468789 / NM_001105078.4; = p.D660H on NM_004991.4) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52969581; called by muse, mutect2, varscan2
- MOCS2 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1175585470, COSV100798968; called by muse, mutect2, varscan2
- MYH7 | c.5160C>T p.N1720= | Splice Region (SNP) | VAF 14/62 reads (23%) | catalogued as rs776666954; called by muse, mutect2
- MYNN | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57754846; called by muse, mutect2, varscan2
- NAV3 | c.5875C>T p.R1959C (on ENST00000397909 / NM_001024383.2; = p.R1937C on NM_014903.6) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs573838509, COSV57091466; called by muse, mutect2, varscan2
- NCOR2 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62300934; called by muse, mutect2, varscan2
- NFE2L1 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV62583573; called by muse, mutect2, varscan2
- NOVA1 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57481787, COSV57482599; called by muse, mutect2, varscan2
- OCRL | c.1491G>C p.W497C | Missense Mutation (SNP) | VAF 95/142 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63981422; called by muse, mutect2, varscan2
- OR10J3 | c.432A>C p.Q144H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV59955113; called by muse, mutect2, varscan2
- OR4N2 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV60052743, COSV60053213; called by muse, mutect2, varscan2
- OR51B4 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766237146, COSV100971278, COSV66517483; called by muse, mutect2, varscan2
- OR6A2 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV60265458; called by muse, mutect2, varscan2
- PACS2 | c.2510G>C p.R837P | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57655561, COSV57657219; called by muse, mutect2, varscan2
- PES1 | c.1423G>C p.G475R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV58829241; called by muse, mutect2
- PIBF1 | c.2010A>C p.Q670H | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58325899; called by muse, mutect2, varscan2
- PIEZO2 | c.6773G>A p.G2258E | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53291961; called by muse, mutect2, varscan2
- PKHD1L1 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65747893; called by muse, mutect2, varscan2
- PLEKHS1 | c.761+1G>A p.X254_splice (on ENST00000369310 / NM_182601.1; = p.X260_splice on NM_024889.5) | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as rs1252477577, COSV63056116; called by muse, mutect2, varscan2
- PLXNA4 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58144744; called by muse, mutect2, varscan2
- POP1 | c.1189A>T p.K397* | Nonsense Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV62893613; called by muse, mutect2, varscan2
- PPP1R9A | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194497; called by muse, mutect2, varscan2
- PPP4R3A | c.2266C>G p.L756V (on ENST00000554943 / NM_001366432.1; = p.L743V on NM_001284280.1) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.146); catalogued as COSV61505692; called by muse, mutect2, varscan2
- PRKACG | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55253021, COSV99598625; called by muse, mutect2, varscan2
- PTPRG | c.2658T>C p.Y886= | Splice Region (SNP) | VAF 18/60 reads (30%) | catalogued as rs1311635157, COSV55652180; called by muse, mutect2, varscan2
- R3HDML | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs201921888; called by muse, mutect2, varscan2
- RASGRF2 | c.2768G>T p.R923L | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54134589, COSV99430118; called by muse, mutect2, varscan2
- RASGRP1 | c.658T>A p.S220T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV60366450; called by muse, mutect2, varscan2
- RASL11A | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767537468, COSV54080793; called by mutect2, varscan2
- RELCH | c.2265G>C p.L755F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56884455; called by muse, mutect2, varscan2
- RGS22 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV62656828; called by muse, mutect2, varscan2
- RTN4IP1 | c.511A>C p.K171Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV64805870; called by muse, mutect2, varscan2
- SDR39U1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52162087; called by muse, mutect2, varscan2
- SEMA3E | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs769248913, COSV57100007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA10 | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV56229050; called by muse, mutect2, varscan2
- SETD2 | c.6751G>C p.D2251H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57444676; called by muse, mutect2, varscan2
- SH3GLB1 | c.570+1G>C p.X190_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as COSV65280385; called by muse, mutect2, varscan2
- SLC25A42 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV59379260, COSV59381045; called by muse, mutect2, varscan2
- SLC25A52 | c.37G>A p.D13N (on ENST00000672005; = p.D3N on NM_001034172.4) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.105); catalogued as COSV52503322, COSV99329559; called by muse, mutect2, varscan2
- SLC35A1 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as COSV65780432; called by muse, mutect2, varscan2
- SMARCAL1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV61922318; called by mutect2, varscan2
- SNIP1 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as COSV56167496; called by muse, mutect2, varscan2
- SNX27 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1298310803, COSV64327005; called by muse, mutect2, varscan2
- SOX14 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60162801; called by muse, mutect2, varscan2
- SOX6 | c.1992C>G p.N664K (on ENST00000528429 / NM_001145819.2; = p.N637K on NM_017508.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57051924; called by muse, mutect2, varscan2
- SPTBN2 | c.5048C>T p.A1683V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.518); catalogued as rs909247644, COSV100017965; called by muse, mutect2, varscan2
- SRCAP | c.6977A>G p.E2326G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs1028295006, COSV52677029; called by muse, mutect2, varscan2
- STRA8 | c.334G>T p.A112S (on ENST00000275764; = p.A90S on NM_182489.2) | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51962346; called by muse, mutect2, varscan2
- SYNM | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60372696; called by muse, mutect2, varscan2
- TADA2A | c.955A>G p.M319V | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs766832434; called by muse, mutect2, varscan2
- TAS2R60 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs919299515, COSV100223514, COSV60331517; called by muse, mutect2, varscan2
- TAS2R7 | c.476G>T p.C159F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV53689927; called by muse, mutect2, varscan2
- TCHH | c.4498G>A p.D1500N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.433); catalogued as COSV64276302; called by muse, mutect2, varscan2
- TGFBR2 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55454718; called by muse, mutect2, varscan2
- TMEM131 | c.1761C>G p.D587E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV51781249, COSV99486789; called by muse, mutect2, varscan2
- TNXB | c.7484C>T p.T2495I (on ENST00000647633; = p.T2248I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0.101); catalogued as COSV64483582; called by muse, mutect2, varscan2
- TREML2 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | catalogued as COSV72439196; called by muse, mutect2, varscan2
- TTC14 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV56009329, COSV56013019; called by muse, varscan2
- TTC14 | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV56013065; called by muse, varscan2
- VCAN | c.10104A>C p.K3368N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54110983; called by muse, mutect2, varscan2
- WIPF1 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV55817847; called by muse, mutect2, varscan2
- WNK1 | c.864A>T p.E288D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60039694; called by muse, mutect2, varscan2
- ZNF16 | c.1908A>T p.K636N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52764775; called by muse, mutect2
- ZNF287 | c.630A>G p.G210= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV67688742; called by muse, mutect2, varscan2
- ZNF318 | c.1189-1G>C p.X397_splice | Splice Site (SNP) | VAF 10/58 reads (17%) | catalogued as COSV58934956; called by muse, mutect2, varscan2
- ZSWIM8 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs746014099, COSV67133590; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1213_1218del p.D405_S406del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- APC | c.5937del p.N1979Kfs*65 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- CALCOCO1 | c.1379_1380del p.S460* | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel
- CDH24 | c.824del p.G275Afs*19 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- CNNM4 | c.1770_1776del p.D591Tfs*37 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel
- DPY19L3 | c.1113_1115del p.D371del | In Frame Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- ELAC2 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2
- FURIN | c.1457A>T p.H486L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLE1 | c.1446_1455+6del p.X482_splice | Splice Site (DEL) | VAF 19/129 reads (15%) | called by mutect2, pindel, varscan2
- GSTT2B | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR2 | c.2246_2252del p.I749Rfs*8 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- JAK2 | c.2973_2992del p.K991Nfs*12 | Frame Shift Del (DEL) | VAF 26/115 reads (23%) | called by mutect2, pindel, varscan2
- LAMB4 | c.944_957del p.D315Afs*16 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- LYST | c.4689-20_4690del p.X1563_splice | Splice Site (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel
- MEGF11 | c.1724G>A p.C575Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MTMR8 | c.629_630del p.S210Wfs*9 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by pindel, varscan2
- RTP5 | c.819del p.G274Afs*209 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.1627_1632del p.I543_N544del | In Frame Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- SPEN | c.2121_2141del p.E707_R713del | In Frame Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- WIF1 | c.791_798delinsCTCCCT p.C264Sfs*10 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by pindel, varscan2*
- ZNF709 | c.272_290del p.P91Lfs*3 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- ABI3 | c.402G>A p.T134= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1348206891, COSV56800247, COSV56800454; called by muse, mutect2, varscan2
- ADPRHL1 | c.996C>T p.D332= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV62910568; called by muse, mutect2, varscan2
- AIFM2 | c.630C>T p.S210= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as COSV57159999; called by muse, mutect2, varscan2
- ALAS1 | c.1011G>A p.G337= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as COSV59628780; called by muse, mutect2, varscan2
- ANP32A | c.159C>T p.G53= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV51189756; called by muse, mutect2, varscan2
- ARMC6 | c.405G>T p.G135= (on ENST00000392336; = p.G110= on NM_033415.4) | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99522882; called by muse, mutect2, varscan2
- ARRDC2 | c.327C>T p.S109= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55845413; called by muse, varscan2
- ATP10A | c.3990C>T p.L1330= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV63520595; called by muse, mutect2, varscan2
- ATP6V0D1 | c.546C>G p.R182= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV52099026; called by muse, mutect2, varscan2
- B4GALNT2 | c.489G>C p.A163= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV55927364, COSV55929323; called by muse, mutect2, varscan2
- CATIP | c.783C>T p.G261= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56823599; called by muse, mutect2, varscan2
- CEP120 | c.1341A>T p.V447= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as COSV60267000; called by muse, mutect2, varscan2
- CNR2 | c.537C>T p.C179= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65693333; called by muse, mutect2, varscan2
- COLEC12 | c.840C>T p.N280= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs370741108; called by muse, mutect2, varscan2
- CPQ | c.18C>T p.F6= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs765822863, COSV55153412; called by muse, mutect2, varscan2
- DOCK2 | c.1689C>T p.S563= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs777636158, COSV99909637; called by mutect2, varscan2
- DVL3 | c.1161C>G p.T387= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV100493468; called by muse, mutect2, varscan2
- GZMH | c.33T>G p.L11= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV53538982; called by muse, mutect2, varscan2
- IVNS1ABP | c.346C>A p.R116= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV62249977, COSV62250175; called by muse, mutect2, varscan2
- LAMA5 | c.2769C>G p.T923= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53365602; called by muse, mutect2
- LONRF2 | c.1833G>A p.A611= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs199722110; called by muse, mutect2, varscan2
- LRIG3 | c.1209A>G p.K403= | Silent (SNP) | VAF 52/229 reads (23%) | catalogued as COSV57867135; called by muse, mutect2, varscan2
- MUC16 | c.7740A>C p.T2580= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs764602942; called by muse, varscan2
- MYO3B | c.2595A>G p.R865= | Silent (SNP) | VAF 31/163 reads (19%) | catalogued as COSV58710186; called by muse, mutect2, varscan2
- MYOM1 | c.2274G>A p.S758= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs774986758, COSV55296498; called by muse, mutect2, varscan2
- NAT2 | c.834T>C p.N278= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV54062538; called by muse, mutect2, varscan2
- NEDD9 | c.903C>T p.H301= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV65222392; called by muse, mutect2, varscan2
- NEPRO | c.306C>A p.G102= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV58723970; called by muse, mutect2, varscan2
- OR2AE1 | c.210T>C p.D70= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV60390646; called by muse, mutect2, varscan2
- OTOP1 | c.1125C>T p.D375= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs539020363; called by muse, mutect2, varscan2
- PLB1 | c.9G>A p.L3= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV59831229; called by muse, mutect2, varscan2
- POLR3C | c.604A>C p.R202= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100492732; called by muse, mutect2, varscan2
- RRP12 | c.1524G>C p.V508= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as COSV59669706; called by muse, mutect2, varscan2
- RTL5 | c.555C>A p.A185= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV65454197; called by muse, mutect2, varscan2
- RTN1 | c.2265T>G p.T755= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV50734341; called by muse, mutect2, varscan2
- STOX1 | c.2031C>A p.G677= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV100057569, COSV53816358; called by muse, mutect2, varscan2
- TBC1D16 | c.1560C>T p.Y520= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs375707260; called by mutect2, varscan2
- TRIM60 | c.1116T>A p.L372= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV61971176; called by muse, mutect2, varscan2
- TRPS1 | c.3393G>A p.V1131= (on ENST00000220888 / NM_001330599.2; = p.V1144= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV55240904; called by muse, mutect2, varscan2
- TTC14 | c.483C>T p.I161= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as COSV56013045; called by muse, varscan2
- WNK1 | c.2652G>T p.A884= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs142528714, COSV60039711; called by muse, mutect2, varscan2
- ZNF169 | c.1083C>T p.L361= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs187190486, COSV61763859, COSV61765450; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1618C>A | Intron (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100800751; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1619C>A | Intron (SNP) | VAF 8/77 reads (10%) | catalogued as COSV100800756; called by muse, mutect2, varscan2
- C3orf84 | c.141+24_141+41del | Intron (DEL) | VAF 26/149 reads (17%) | called by mutect2, pindel
- ELP4 | c.1147-19953G>C | Intron (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2
- FRMPD2B | n.879G>A | RNA (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- GLRA2 | c.270+132C>A | Intron (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99490036; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.723C>T | RNA (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- VPS13C | c.-1C>G | 5'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99826532; called by muse, mutect2, varscan2
